Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6524, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6524-01A (Primary Tumor).

Examination: Histopathological examination

Material: Total resection of organ – stomach

TCGA – D7 – 6524

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the pyloric part of the stomach

Examination performed on:

Macroscopic description:

The tested material contained the stomach, after having been excised along the greater curvature sized 20.4 x 18.8 cm. A thickened wall sized 10.6 x 11.7 cm found in the parapyloric region, 1.2 cm to the proximal boundary, 1.1 cm to the distal boundary.

Microscopic description:

Adenocarcinoma invasivum (G3) ventriculi.

The neoplastic invasion spreads the full thickness of the stomach wall penetrating into the fat tissue.

The incision line in the esophagus is free of hyperplasia at the side of the pylorus within the neoplastic proliferation. (Mixed type according to Laurén's classification).

Outside tumour: gastritis chronica. Omentum – hyperaemia.

Lymph nodes:

(pericardium): metastases carcinomatosae in lymphonodo No (I / 1). (lesser curvature): metastases carcinomatosae in

lymphonodis No (III / VIII). (greater curvature): metastases carcinomatosae in lymphonodis No (II / VI). (peripylorum):

lymphonodulitis reactiva No I.

Histopathological diagnosis:

Adenocarcinoma invasivum ventriculi (G3), pT2, pN1. Invasive adenocarcinoma of the stomach.

Metastases carcinomatosae in lymphonodis No VI / XVI. Cancer metastases in the lymph nodes

Source: NCI Genomic Data Commons file 9741c94b-5bb5-4f8c-8da3-0672d1cc3bc6 (TCGA-D7-6524.C0B8A70D-B8B4-4C81-BB96-9038B66A1DA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).